HCMI case HCM-BROD-0958-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Ovary. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5fd76dd8-87e1-422d-bac2-63e447ca3ba4

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Dead; Days to death: 1,435 days (3.9 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Classification of tumor: primary; Age at diagnosis: 62.8 years (22,920 days); AJCC staging edition: 7th; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: No; Sites of involvement: Pelvis / Ovary, Left / Fallopian Tube, Left.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,346 days (3.7 years); Days to treatment end: 1,429 days (3.9 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/6; ICD-10 code: C78.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 62.8 years (22,920 days); Peritoneal fluid cytological status: Malignant; Sites of involvement: Ovary, Left / Fallopian Tube, Left / Uterus / Omentum / Vagina.
   Pathology details: Tumor largest dimension diameter: 8 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bevacizumab + Carboplatin + Doxorubicin + Gemcitabine + Olaparib + Paclitaxel + Vinorelbine; Treatment intent type: Maintenance Therapy; Days to treatment start: 31 days; Days to treatment end: 1,291 days (3.5 years); Treatment outcome: Progressive Disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Pelvis, NOS; Days to progression: 0 days.
- Days to follow up: 1,435 days (3.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contacts recording only the day: day 1,338, day 1,429.

Molecular and laboratory tests
- BRCA1 mutation, nos (Targeted Sequencing): Negative.
- BRCA2 mutation, nos (Targeted Sequencing): Negative.
- CA-125: 17.
- TP53 (IHC): Overexpressed.
- WT1 (IHC): Negative.

Other clinical attributes
- Day 0: Risk factors: Endometriosis.
- Timepoint category: Initial Diagnosis; Weight: 68 kg; Height: 160 cm; BMI: 27.
- Timepoint category: Prior to Diagnosis; Risk factors: Hereditary Breast Cancer.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-BROD-0958-C56-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0958-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
